Somatic mutation profile of tumor specimen TARGET-10-PARPGL-09A (aliquot TARGET-10-PARPGL-09A-01D) from TARGET case TARGET-10-PARPGL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.0 years (4,759 days).
Specimen TARGET-10-PARPGL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09867f5f-f69b-4910-a509-12a3ad74e54c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPGL-10A (Blood Derived Normal), aliquot TARGET-10-PARPGL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e27b451-782a-400e-a60c-fe06db193dfe

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.5087C>T p.T1696M | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751030969, COSV62104951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2C | c.9067A>G p.S3023G | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs756327170; called by muse, mutect2, varscan2
- ETF1 | c.100A>T p.M34L | Missense Mutation (SNP) | VAF 120/219 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- GRM7 | c.1756T>G p.W586G | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- H2BC6 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV10-54 | chr22:22215259 del GCCTCAGTGCTCACACAGT | Missense Mutation (DEL) | VAF 24/36 reads (67%) | called by mutect2, varscan2
- LIMA1 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- LSM14A | c.826_827insTT p.R276Lfs*16 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- ZNF318 | c.6664A>G p.I2222V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AL121899.2 | c.1128G>A p.P376= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs191199076; called by muse, mutect2, varscan2
- EVPLL | c.195G>A p.P65= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs774647683, COSV67684987; called by muse, mutect2, varscan2
- FFAR3 | c.63C>T p.Y21= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- TACC2 | c.7335A>G p.P2445= (on ENST00000334433; = p.P523= on NM_006997.4) | Silent (SNP) | VAF 101/209 reads (48%) | catalogued as rs1430079078; called by muse, mutect2, varscan2
- ANK2 | c.2377-146G>A | Intron (SNP) | VAF 17/45 reads (38%) | catalogued as rs765921458; called by muse, mutect2, varscan2
- ERCC6L2 | chr9:96020828 ins GGA | 3'Flank (INS) | VAF 68/153 reads (44%) | called by mutect2, pindel*, varscan2
- GABPB1 | c.-1+865_-1+873delinsGCCTCTCAA | Intron (ONP) | VAF 15/30 reads (50%) | called by pindel, varscan2*
